Somatic mutation profile of tumor specimen TARGET-10-PARATY-09A (aliquot TARGET-10-PARATY-09A-01D) from TARGET case TARGET-10-PARATY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (949 days).
Specimen TARGET-10-PARATY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fffa5de5-4394-436c-ac24-76e6a8264584.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARATY-10A (Blood Derived Normal), aliquot TARGET-10-PARATY-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcf6d72d-9657-4959-8204-5bdfe0d97f11

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LZTR1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs869320686, CM154934, COSV53144758; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C2CD4C | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59967949; called by muse, mutect2, varscan2
- EPHA1 | c.1198A>T p.T400S | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV51971566; called by muse, mutect2
- GAA | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.124); catalogued as COSV56412767; called by muse, mutect2
- MAT1A | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as rs767906537, CM1311638, COSV100944441; called by muse, mutect2, varscan2
- PCNX1 | c.4016G>A p.R1339Q | Missense Mutation (SNP) | VAF 30/181 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs201817854, COSV53092154; called by muse, mutect2, varscan2
- CFAP52 | c.1257C>T p.G419= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as rs768830852; called by muse, mutect2, varscan2
- CRTAP | c.498C>T p.A166= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as rs1309501247, COSV58013323; called by muse, mutect2, varscan2
- PAX9 | c.852G>A p.S284= | Silent (SNP) | VAF 39/166 reads (23%) | catalogued as rs755740078, COSV58717853; called by muse, mutect2, varscan2
- IGHV1-69D | chr14:106762091 ins ATAT | 3'Flank (INS) | VAF 11/101 reads (11%) | called by mutect2, pindel, varscan2
- LHX8 | c.995-110C>T | Intron (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2
